Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A7T8, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A7T8-01A (Primary Tumor).

[page 1 of 2]
Anatomic Pathology/Cytology Document State: (version)

Update Date/Time:
Final 1

Patient Name:
DOB/Age/Gender:
Location Responsible Staff:

MRN:
Male Provider:

Service Date/Time:

ICD 0.3
Oligoastrocytoma, grade III 938213
Date ^{4/22} Brain, supratentorial NOS C71.0
path ^{4/22} Brain, frontal lobe C71.1
JW 4/22/14

PATHOLOGICAL DIAGNOSIS:

A. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSIES: GLIOMA WITH ATYPICAL FEATURES.
B. BRAIN, RIGHT FRONTAL, EXCISION: MIXED OLIGOASTROCYTOMA, ANAPLASTIC. MIB-1 PROLIFERATION INDEX 3%.
SEE COMMENT.

Operation/Specimen: Brain, right frontal, excision.
Clinical History and Pre-Op Dx: year old man with large right frontal brain tumor with focal enhancement.

GROSS PATHOLOGY:

A. Received fresh, three fragments, 1.5 cm across in aggregate.
Soft, mucinous, grayish-pink. #1-5.

INTRAOPERATIVE CONSULTATION: Brain, smears: Glioma.

B.

SPECIMEN: Brain tumor permanent.

FIXATIVE: Saline.

GENERAL: Two glassy to pale tan soft tissue fragments, 1.0 cm. in greatest dimension, and 2.0 x 1.0 x 0.7 cm. Largest fragment is sectioned.

SECTIONS: All submitted in cassettes 6 and 7.

COMMENT: In part A there is a moderately cellular neoplastic proliferation of glial cells. The neoplastic cells are predominantly round, somewhat pleomorphic and disposed in a mucinous background with microcystic change. Mitotic figures are rarely observed and microvascular cellular proliferation or necrosis is absent.

In part B there are focal areas of a similar neoplasia. In addition, there are zones with a better defined astrocytic or oligodendroglial phenotype. In this specimen, however, there are zones of tumor necrosis and microvascular cellular proliferation.

The findings are interpreted as a glial neoplastic proliferation, probably mixed oligoastrocytic but predominantly astrocytic, that has undergone focal anaplastic transformation (WHO grade III).

Microvascular proliferation and mitoses in the WHO classifications of astrocytomas merit a grade IV category.

IMMUNOHISTOCHEMISTRY: Immunoperoxidase methods for GFAP, CD34, p53, and MIB-1 were performed on sections from block #7. The GFAP demonstrates sparse gliofibrillogenesis by neoplastic cells. The CD34 depicts the rich vascularity within the neoplasm. About 5% of cells over-express the p53 antigen. With the MIB-1, a proliferation index of 3% is determined in the more cellular areas.

TISSUE COMMITTEE CODE:

ICD9: 191

[page 2 of 2]
BILLING CODES:

Dual/Syncruous Primary Noted		✓

Source: NCI Genomic Data Commons file 2ffb5afe-599c-4b16-945b-0f755b4dd41f (TCGA-DU-A7T8.342A92BA-BEF9-40C6-85FF-71328B8C1DCF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).